Somatic mutation profile of tumor specimen TCGA-EJ-5505-01A (aliquot TCGA-EJ-5505-01A-01D-1576-08) from TCGA case TCGA-EJ-5505, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.9 years (21,164 days).
Specimen TCGA-EJ-5505-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 250728b2-40cf-41c6-a32a-43d22952c40d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5505-10A (Blood Derived Normal), aliquot TCGA-EJ-5505-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05dc61b5-318c-473a-80a3-5cfac75cabc4

The open-access MAF lists 30 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 4, Nonsense Mutation 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAC1 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 16/290 reads (6%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV61821906; called by muse, mutect2
- SPOP | c.260A>C p.Y87S | Missense Mutation (SNP) | VAF 48/263 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs1057519971, COSV100753468, COSV61652670, COSV61653014; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADRA1D | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.092); catalogued as COSV65240319, COSV65241802; called by muse, mutect2, varscan2
- ASH1L | c.681T>A p.C227* | Nonsense Mutation (SNP) | VAF 71/264 reads (27%) | catalogued as COSV64205904; called by muse, mutect2, varscan2
- ASIC4 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV61731128; called by muse, mutect2, varscan2
- ATP6V1C2 | c.992A>C p.N331T (on ENST00000272238 / NM_001039362.2; = p.N285T on NM_144583.4) | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55349486; called by muse, mutect2, varscan2
- BRAF | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56085407; called by muse, mutect2, varscan2
- C16orf54 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs190639748, COSV61476624; called by muse, mutect2, varscan2
- CNOT1 | c.398T>G p.L133R | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57765599; called by muse, mutect2, varscan2
- DNMT1 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV61576902; called by muse, mutect2, varscan2
- DOCK10 | c.2041C>A p.H681N | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV51352271; called by muse, mutect2, varscan2
- DUSP7 | c.827A>G p.N276S | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs550638572, COSV56588690; called by muse, mutect2, varscan2
- HEPHL1 | c.1171T>C p.W391R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59889824; called by muse, mutect2, varscan2
- ITGAD | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV66756931; called by muse, mutect2, varscan2
- LIG1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 79/376 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV54389832; called by muse, mutect2, varscan2
- MLLT3 | c.122A>G p.H41R | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.069); catalogued as COSV63495306; called by muse, mutect2, varscan2
- NUP133 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV54568685; called by muse, mutect2, varscan2
- OR4D5 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs755011604, COSV58305823; called by muse, mutect2, varscan2
- PI16 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.704); catalogued as rs139393851; called by muse, mutect2, varscan2
- RFK | c.365A>T p.D122V | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65060706; called by muse, mutect2
- RTN4R | c.492C>A p.N164K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50380709; called by muse, mutect2, varscan2
- TIMELESS | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs776587905, COSV57509380; called by muse, mutect2, varscan2
- XRRA1 | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV58496422; called by muse, mutect2, varscan2
- ZBBX | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 85/431 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100285025, COSV56783813; called by muse, mutect2, varscan2
- EFHC1 | c.109_124del p.Y37Vfs*6 | Frame Shift Del (DEL) | VAF 29/181 reads (16%) | called by mutect2, pindel, varscan2
- ACTRT3 | c.273T>C p.Y91= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as COSV57753849; called by muse, mutect2, varscan2
- BSX | c.570C>T p.R190= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1264114373, COSV58005149; called by muse, mutect2, varscan2
- HCFC1 | c.1653T>G p.A551= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV60069820; called by muse, mutect2, varscan2
- HSPA1B | c.1761C>G p.A587= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs754714469, COSV65128231; called by muse, mutect2, varscan2
- DCHS2 | n.1061G>C | RNA (SNP) | VAF 42/184 reads (23%) | catalogued as COSV59719401; called by muse, mutect2, varscan2
